Somatic mutation profile of tumor specimen TCGA-BS-A0TI-01A (aliquot TCGA-BS-A0TI-01A-11D-A10B-09) from TCGA case TCGA-BS-A0TI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 64.9 years (23,705 days).
Specimen TCGA-BS-A0TI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32aba1a5-00d6-454f-a2a2-4001637a08b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0TI-10A (Blood Derived Normal), aliquot TCGA-BS-A0TI-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ce97f31-96e2-46b1-a5ff-c3769fa0c8a3

The open-access MAF lists 92 somatic variants for this specimen: 79 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 68, Silent 13, Frame Shift Del 4, Nonsense Mutation 4, In Frame Del 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 356/448 reads (79%) | catalogued as rs869312778, COSV64294055, COSV64304098; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 29/44 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ACTN1 | c.2227A>G p.I743V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV51996077, COSV51998313; called by muse, mutect2, varscan2
- AKAP6 | c.1254del p.K418Nfs*4 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as COSV55219581, COSV55234882; called by mutect2, pindel, varscan2
- AKAP9 | c.5522A>G p.N1841S (on ENST00000359028; = p.N1809S on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62358853; called by muse, mutect2, varscan2
- ANO10 | c.1861C>G p.Q621E | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.068); catalogued as COSV52736767; called by muse, mutect2, varscan2
- AP4E1 | c.2175T>G p.D725E | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.026); catalogued as COSV55920474; called by muse, mutect2, varscan2
- APOB | c.2131T>C p.F711L | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs746180039, COSV51954560; called by muse, mutect2, varscan2
- ARAP2 | c.410G>T p.S137I | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.075); catalogued as COSV58293074; called by muse, mutect2, varscan2
- CATSPER1 | c.1736C>A p.S579Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56413758; called by muse, mutect2, varscan2
- CCDC157 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs746672484, COSV57842321; called by muse, mutect2, varscan2
- CDC27 | c.1471C>G p.L491V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as COSV50376650, COSV50399590; called by muse, mutect2, varscan2
- CDH17 | c.2035C>A p.P679T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50325598, COSV50343298; called by muse, mutect2, varscan2
- CNTRL | c.4703T>G p.L1568R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53054016; called by muse, mutect2, varscan2
- COG1 | c.2221C>G p.P741A | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.124); catalogued as COSV55432208; called by muse, mutect2, varscan2
- COL26A1 | c.562G>C p.A188P (on ENST00000313669 / NM_001278563.3; = p.A186P on NM_133457.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.648); catalogued as COSV58133284; called by muse, mutect2, varscan2
- COL6A2 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs768542626, COSV56009459, COSV56010692; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRTC3 | c.143A>G p.Q48R | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV51601003; called by muse, mutect2, varscan2
- CYLC1 | c.518A>T p.K173M | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV61416332; called by muse, mutect2, varscan2
- CYP4A22 | c.860G>A p.R287K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.099); catalogued as COSV53742652; called by muse, mutect2, varscan2
- DDX18 | c.1633A>C p.K545Q | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV54309403; called by muse, mutect2, varscan2
- EPB41L1 | c.451T>G p.W151G | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52445658; called by muse, mutect2, varscan2
- FAM91A1 | c.1237T>G p.S413A | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100593798, COSV58240071; called by muse, mutect2, varscan2
- FRAS1 | c.12038A>C p.*4013Sext*10 | Nonstop Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV53652223; called by muse, mutect2, varscan2
- FZD3 | c.40A>G p.T14A | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV53537947; called by muse, mutect2, varscan2
- GLB1L3 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs781228936, COSV68393520; called by muse, mutect2, varscan2
- GNPTAB | c.2070G>T p.Q690H | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV68449999; called by muse, mutect2
- GPR174 | c.353G>T p.W118L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV52131524, COSV52134612; called by muse, mutect2, varscan2
- HABP2 | c.1143G>T p.K381N | Missense Mutation (SNP) | VAF 95/121 reads (79%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV63638152; called by muse, mutect2, varscan2
- HNRNPL | c.829A>T p.K277* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV55495668; called by muse, mutect2, varscan2
- IL6 | c.619A>T p.R207W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51734451; called by muse, mutect2, varscan2
- INSC | c.464T>A p.V155E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV65413387; called by muse, mutect2
- IRS1 | c.967T>G p.S323A | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV59340620; called by muse, mutect2, varscan2
- ITPR1 | c.2130C>G p.S710R (on ENST00000354582; = p.S695R on NM_002222.7) | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV57005895; called by muse, mutect2, varscan2
- KDM8 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760996994, COSV53732197; called by muse, mutect2, varscan2
- KIT | c.2216G>A p.R739K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.429); catalogued as COSV55424070; called by muse, mutect2, varscan2
- KLHL23 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs764264802, COSV55869914; called by muse, mutect2, varscan2
- KMT2C | c.13750C>T p.R4584W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747850540, COSV51428250; called by muse, mutect2, varscan2
- KRTAP10-10 | c.741G>T p.Q247H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV59958817, COSV59972036; called by muse, mutect2, varscan2
- KRTAP19-8 | c.55G>C p.G19R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as COSV66998532; called by muse, mutect2
- LDB2 | c.896T>G p.V299G | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV58784098; called by muse, mutect2, varscan2
- LRRC18 | c.721A>T p.I241F | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV53286109; called by muse, mutect2, varscan2
- MROH2B | c.2971A>G p.K991E | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as rs1321259354, COSV68189979; called by muse, mutect2, varscan2
- MTMR1 | c.446T>C p.V149A | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.163); catalogued as COSV64899946; called by muse, mutect2
- MUC16 | c.34570A>T p.S11524C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV67496844; called by muse, mutect2, varscan2
- MYH2 | c.4142A>G p.Y1381C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV55449575; called by muse, mutect2, varscan2
- NCAN | c.3766A>G p.I1256V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as COSV53059908; called by muse, mutect2, varscan2
- NCR2 | c.90T>A p.S30R | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV66101413; called by muse, mutect2, varscan2
- OR9A4 | c.442T>A p.S148T | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.724); catalogued as COSV71886141; called by muse, mutect2, varscan2
- PAPPA | c.2042T>G p.V681G | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as COSV60292697; called by muse, mutect2, varscan2
- PDE1A | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.773); catalogued as COSV59525689; called by muse, mutect2, varscan2
- PDE9A | c.563T>G p.V188G | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV52332063; called by muse, mutect2, varscan2
- PDGFRA | c.2914A>G p.S972G | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1353514444, COSV57274923; called by muse, mutect2, varscan2
- PDGFRB | c.186G>A p.W62* | Nonsense Mutation (SNP) | VAF 10/17 reads (59%) | catalogued as COSV55801147; called by muse, mutect2, varscan2
- PIKFYVE | c.1891T>C p.S631P | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52249692; called by muse, mutect2, varscan2
- PIR | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66816412; called by muse, mutect2, varscan2
- PLEKHA6 | c.2713C>G p.L905V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.952); catalogued as COSV55340781; called by muse, mutect2, varscan2
- POLD3 | c.1153C>G p.R385G | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55242880, COSV55246085; called by muse, mutect2, varscan2
- PTK2 | c.2576A>G p.H859R | Missense Mutation (SNP) | VAF 97/449 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV61793372; called by muse, mutect2, varscan2
- PUM3 | c.454A>C p.K152Q | Missense Mutation (SNP) | VAF 17/403 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as COSV67397568; called by muse, mutect2
- SLC10A5 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771582510, COSV72828514; called by muse, mutect2, varscan2
- SMG7 | c.1910C>G p.T637S | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV61634587; called by muse, mutect2, varscan2
- SOX10 | c.1369C>A p.Q457K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62807563; called by muse, mutect2, varscan2
- SYNPO2 | c.3521A>G p.E1174G | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.234); catalogued as COSV61118279; called by muse, mutect2, varscan2
- SYT5 | c.463del p.D155Tfs*15 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as COSV100845888; called by mutect2, pindel, varscan2
- TAF9B | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59372463; called by muse, mutect2, varscan2
- TJP3 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV53665923; called by muse, mutect2, varscan2
- TMEM92 | c.400A>C p.T134P | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.367); catalogued as COSV55946949; called by muse, mutect2, varscan2
- TSGA10 | c.870T>A p.S290R | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV61821982, COSV61825944; called by muse, mutect2, varscan2
- TTC27 | c.557T>C p.L186S | Missense Mutation (SNP) | VAF 99/205 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58656981; called by muse, mutect2, varscan2
- TTN | c.59630C>A p.A19877E (on ENST00000591111; = p.A12453E on NM_003319.4) | Missense Mutation (SNP) | VAF 51/144 reads (35%) | PolyPhen benign (0.134); catalogued as COSV60374549; called by muse, mutect2, varscan2
- ZIM3 | c.272G>T p.W91L | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.051); catalogued as COSV54147049; called by muse, mutect2
- ZNF222 | c.133C>A p.L45I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51828650; called by muse, mutect2, varscan2
- CTPS2 | c.921_957del p.Y307* | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel
- FREM2 | c.8699_8722del p.V2900_G2907del | In Frame Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel
- GNPDA2 | c.74_82del p.I25_F27del | In Frame Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.2731del p.T911Lfs*10 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- TRBV19 | c.70A>C p.T24P | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- TRBV20-1 | c.77T>A p.I26N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- APPL2 | c.1183C>T p.L395= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as rs772695100, COSV51594193; called by muse, mutect2, varscan2
- CNKSR2 | c.1017A>G p.T339= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV54267459; called by muse, mutect2, varscan2
- FBXL18 | c.1557C>T p.V519= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs759380957, COSV66107588; called by muse, mutect2, varscan2
- GLMN | c.1207T>C p.L403= | Silent (SNP) | VAF 49/149 reads (33%) | catalogued as COSV64861765; called by muse, mutect2, varscan2
- KMT2B | c.4501C>T p.L1501= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs1327330012, COSV55870446; called by mutect2, varscan2
- MOGAT1 | c.405C>A p.G135= | Silent (SNP) | VAF 12/163 reads (7%) | catalogued as COSV71479885, COSV71480156; called by muse, mutect2
- NAGK | c.97C>T p.L33= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV54904622; called by muse, mutect2, varscan2
- PREX1 | c.1860C>T p.N620= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV64257288; called by muse, mutect2
- RAB37 | c.174C>T p.I58= | Silent (SNP) | VAF 28/35 reads (80%) | catalogued as rs749871961, COSV61194680, COSV61198472; called by muse, mutect2, varscan2
- SERPINE3 | c.588C>T p.G196= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV68545909; called by muse, mutect2
- TAPBPL | c.597C>G p.S199= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV56948791; called by muse, mutect2, varscan2
- TECTA | c.1197A>G p.R399= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV50815192; called by muse, mutect2
- ZNF563 | c.672G>C p.P224= | Silent (SNP) | VAF 41/114 reads (36%) | catalogued as COSV53372409; called by muse, mutect2, varscan2
